CCG case CUPP-B6BM — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b4c9cc59-d65e-47df-a598-0e038f6e4cf5

Demographics
Sex at birth: female; Race: asian; Country of residence at enrollment: Canada; Year of birth: 1960; Vital status: Dead; Days to death: 189 days; Year of death: 2014; Cause of death: Cancer Related.

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Retroperitoneum; Classification of tumor: metastasis; Age at diagnosis: 53.6 years (19,583 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical N: N0; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Sites of involvement: Retroperitoneum.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R2; Timepoint category: First Treatment.
2. Endometrioid carcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Ovary; Laterality: Right; Classification of tumor: Synchronous primary; Age at diagnosis: 53.8 years (19,644 days); Year of diagnosis: 2013; Days to diagnosis: 61 days; AJCC staging edition: 7th; AJCC pathologic stage: Stage IA.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 61 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Progression of the retroperitoneum (histology not recorded by GDC). Age at diagnosis: 53.9 years (19,672 days); Year of diagnosis: 2013; Days to diagnosis: 89 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Partial Response.

Follow-up (2 entries)
- Day 89 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Retroperitoneum; Days to progression: 89 days.
- Days to follow up: 189 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 56 kg; Height: 159 cm; BMI: 22.2.
- Timepoint category: Prior to Diagnosis; Comorbidities: Other Cancer within 5 Years.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B6BM-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B6BM-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
